CCDI case PBCMEL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/aa0127ca-93b1-4194-94e5-328db185ac3b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.0 years (3,636 days).

Biospecimens (3 samples)
- Sample 0DV2QW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV2R9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV2RY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
